Gene-level copy-number profile of tumor specimen HTMCP-03-06-02145-01B from CGCI case HTMCP-03-06-02145, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.7 years (19,986 days).
Specimen HTMCP-03-06-02145-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1df19525-7c57-4104-a6f6-5869006d45d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02145-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/24763dac-c0ee-4e94-b3c4-d9ae7f076418

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 2,743; copy number 2: 29,030; copy number 3: 19,107; copy number 4: 4,009; copy number 5: 2,237; copy number 6: 1,068; copy number 7: 65; copy number 8: 40; copy number 9: 1; copy number 10: 3; copy number 15: 3; copy number 18: 4; copy number 24: 50.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr7:74,741,457–74,742,121, 1 gene (within-gene range 0–2): PHBP15.
- chr7:74,894,116–74,897,835, 2 genes: PMS2P5, Y_RNA.
- chr8:7,341,826–7,385,558, 3 genes (within-gene range 0–2): AC130360.1, ZNF705G, DEFB108C.
- chr8:12,374,366–12,375,546, 1 gene (within-gene range 0–1): AC087203.1.
- chr9:42,566,679–42,714,539, 7 genes: BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr18:50,879,080–51,845,628, 14 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,464 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,533,749–120,355,148, 23 genes, copy number 7: GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1.
- chr1:143,419,625–174,995,308, 1,100 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr1:248,269,917–248,937,043, 39 genes, copy number 5–6: OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:16,149,251–16,149,394, 1 gene, copy number 5: AC174048.1.
- chr2:96,021,946–96,039,451, 1 gene, copy number 5 (within-gene range 3–5): GPAT2.
- chr3:90,184,634–198,123,232, 1,756 genes, copy number 5–6 (broad region; genes not listed).
- chr5:16,615,926–16,681,905, 1 gene, copy number 5 (within-gene range 4–5): AC024588.1.
- chr5:16,661,907–16,941,951, 4 genes, copy number 5: MYO10, RNA5SP179, RPS26P28, RNU6-660P.
- chr7:75,092,573–75,149,817, 1 gene, copy number 6: GTF2IRD2B.
- chr8:12,290,071–12,318,316, 2 genes, copy number 5–6: DEFB131D, DEFB130A.
- chr8:12,356,136–12,359,391, 1 gene, copy number 5: ZNF705CP.
- chr9:41,760,088–41,764,175, 1 gene, copy number 9: AL162731.1.
- chr12:57,457,596–57,547,224, 10 genes, copy number 5 (within-gene range 3–5): AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2.
- chr12:67,709,047–72,670,758, 96 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr14:22,197,446–22,482,959, 1 gene, copy number 5 (within-gene range 4–5): AC244502.1.
- chr14:22,332,922–22,503,814, 37 genes, copy number 5: AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr15:28,506,625–28,579,400, 6 genes, copy number 8–15: ABCB10P4, GOLGA8G, Metazoa_SRP, AC138749.1, AC138749.2, HERC2P11.
- chr15:101,922,042–101,979,093, 9 genes, copy number 5–10: OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr18:45,669,367–49,851,059, 95 genes, copy number 7–24 (within-gene range 1–24) (broad region; genes not listed).
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.
- chr19:40,379,271–40,808,434, 23 genes, copy number 5 (within-gene range 4–5): HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA, MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4, EGLN2.
- chr19:41,114,432–41,444,765, 24 genes, copy number 5: CYP2F1, CYP2T3P, RPL36P16, RN7SL718P, CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P, TGFB1, AC011462.5, CCDC97, AC011462.1, TMEM91, B9D2, AC011462.4, EXOSC5, BCKDHA, AC011462.3, AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4.
- chr19:43,401,496–43,852,017, 23 genes, copy number 5: TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283.
- chr19:44,613,563–45,410,737, 46 genes, copy number 5 (within-gene range 4–5): IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7, MARK4, PPP1R37, EIF5AP3, AC005757.1, NKPD1, TRAPPC6A, BLOC1S3, EXOC3L2, CKM, RPS16P9, KLC3, ERCC2, PPP1R13L, POLR1G.
- chr19:55,072,020–55,709,858, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:10,122,273–10,137,004, 2 genes, copy number 6: CR382287.1, CDRT15P8.
- chr22:41,998,725–45,341,955, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
